HCMI case HCM-EXPT-0937-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/5a4beafc-8663-4456-a999-77721f072f44

Demographics
Sex at birth: female; Year of birth: 1976.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 38.9 years (14,198 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-0937-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-0937-C50-01A-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-0937-C50-01A-S1-HE: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
